MMRF case MMRF_1698 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/4870fbc0-ac61-4e70-96a8-4d1e0a082185

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.7 years (21,798 days); ISS stage: III; Days to last known disease status: 870 days (2.4 years); Days to last follow up: 870 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days; Days to treatment end: 127 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 129 days; Days to treatment end: 129 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 8.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 465 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.069 mg/dL; Immunoglobulin G 107 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 8.35 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 5.7 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.13 mmol/L; Albumin 24 g/L; Total Protein 17.1 g/dL; Glucose 4.18 mmol/L; C-Reactive Protein 0.87 mg/dL.
- Day 92 (ECOG 1): M Protein 5.03 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 479 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.073 mg/dL; Immunoglobulin G 78.8 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 5.91 µg/mL; Lactate Dehydrogenase 3.87 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.13 mmol/L; Albumin 31 g/L; Total Protein 10.6 g/dL; Glucose 4.84 mmol/L.
- Day 186 (ECOG 1): M Protein 2.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 94.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.453 mg/dL; Immunoglobulin G 33.6 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 4.02 µkat/L; Hemoglobin 5.83 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 124 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 36 g/L; Total Protein 8.5 g/dL; Glucose 4.51 mmol/L.
- Day 270 (ECOG 0): M Protein 1.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.094 mg/dL; Immunoglobulin G 17.8 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7.7 g/dL; Glucose 4.62 mmol/L.
- Day 375 (ECOG 0): M Protein 0.64 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.02 mg/dL; Immunoglobulin G 18.8 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.99 µg/mL; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 4.02 mmol/L.
- Day 466 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.39 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 4.18 mmol/L.
- Day 536 (ECOG 0): M Protein 0.42 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.47 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 78.7 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 4.07 mmol/L.
- Day 632 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.46 mg/dL; Immunoglobulin G 18.3 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.45 mmol/L; Albumin 42 g/L; Total Protein 7.9 g/dL; Glucose 5.12 mmol/L.
- Day 694 (ECOG 1): M Protein 0.45 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 15.8 g/L; Immunoglobulin A 1.43 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 786 (ECOG 0): M Protein 0.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 18.5 g/L; Immunoglobulin A 1.7 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 4.68 mmol/L.
- Day 870 (ECOG 0): M Protein 0.62 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Immunoglobulin G 20.2 g/L; Immunoglobulin A 1.79 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.1 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day 0: Weight: 75 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1698_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1698_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
